CCDI case PBBZZA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/57dc9ae1-03be-4270-a1ef-128f42e31782

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain stem; Age at diagnosis: 15.4 years (5,634 days).

Biospecimens (3 samples)
- Sample 0DM8U3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM8UB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DM8VV: Tissue type: Tumor; Specimen type: Solid Tissue.
